Surgical pathology report (de-identified scan), TCGA case TCGA-24-1842, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1842-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT
FINAL

DIAGNOSIS:

- A. "DIAPHRAGM NODULE," BIOPSY (FS1)
- HIGH GRADE SEROUS CARCINOMA
- B. UTERUS, LEFT OVARY AND FALLOPIAN TUBE, HYSTERECTOMY AND LEFT SALPINGOOPHORECTOMY
- LEFT OVARY:
- HIGH GRADE SEEROUS CARCINOMA
- LEFT FALLOPIAN TUBE:
- HIGH GRADE SEROUS CARCINOMA INVOLVING THE MUSCULAR WALL OF THE TUBE (MUCOSA
NEGATIVE FOR TUMOR)
- UTERUS:
- METASTATIC HIGH GRADE SEROUS CARCINOMA, INVOLVING SEROSA AND MYOMETRIUM
- EXTENSIVE MYOMETRIAL LYMPHVASCULAR SPACE INVASION BY HIGH GRADE SEROUS
CARCINOMA
- PROLIFERATIVE ENDOMETRIUM
- LEIOMYOMATA, LARGER = 1.5 CM
- HISTOLOGICALLY UNREMARKABLE CERVIX
- NO VAGINAL OR BLADDER TISSUE IDENTIFIED
- C. RIGHT OVARY AND FALLOPIAN TUBE, SALPINGO-OOPHORECTOMY
- HIGH GRADE SEROUS CARCINOMA INVOLVING OVARY AND FALLOPIAN TUBE
- D. "RECTAL TUMOR," EXCISION
- HIGH GRADE SEROUS CARCINOMA
- NO BOWEL MUCOSA IDENTIFIED
- E. LYMPH NODES, RIGHT PELVIC, EXCISION
- METASTATIC HIGH GRADE SEROUS CARCINOMA IN FOUR OF SIX LYMPH NODES (4/6)
- EXTRACAPSULAR EXTENSION IDENTIFIED
- F. LYMPH NODES, LEFT PELVIC, EXCISION
- METASTATIC HIGH GRADE CARCINOMA IN FIVE OF SEVEN LYMPH NODES (5/7)
- G. LYMPH NODES, LEFT PERIAORTIC, EXCISION
- METASTATIC HIGH GRADE SEROUS CARCINOMA IN EIGHT OF NINE LYMPH NODES (8/9)

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

- H. LYMPH NODES, RIGHT PERIAORTIC, EXCISION
- METASTATIC HIGH GRADE SEROUS CARCINOMA IN THREE OF FIVE LYMPH NODES (3/5)
- I. OMENTUM, GASTROCOLIC, OMENTECTOMY
- METASTATIC HIGH GRADE SEROUS CARCINOMA
- LARGEST METASTATIC FOCUS = 3.7 CM

By this signature, I attest that the above diagnosis is based upon my personal

Intraoperative Consultation:

FS1: Diaphragm nodule, biopsy
- "High grade carcinoma, favor Mullerian origin," by

Microscopic Description and Comment:

Microscopic examination substantiates the above cited diagnosis.

History:

The patient is a with a large pelvic mass. Operative procedure: Total abdominal hysterectomy, bilateral salpingo-oophorectomy, tumor debulking, and omentectomy.

Specimen(s) Received:

A: DIAPHRAGM NODULE
B: UTERUS, CERVIX, LEFT TUBES AND OVARIES, UPPER VAGINA AND BLADDER
C: RIGHT TUBE AND OVARY
D: RECTAL TUMOR
E: LYMPH NODE, RIGHT PELVIC
F: LYMPH NODE, LEFT PELVIC
G: LYMPH NODE, LEFT PERIAORTIC
H: LYMPH NODE, RIGHT PERIAORTIC
I: GASTROCOLIC OMENTUM

Gross Description:

The specimens are received in nine formalin-filled containers each labeled The first container is labeled "diaphragm nodule (FS1)." It holds a discoid piece of firm, tan-white tissue measuring 1.6 x 1.2 x 0.1 cm.

The second container is labeled "#2 cervix, uterus, left fallopian tube/ovary, upper vagina, and bladder." It holds a uterus measuring 10.5 cm from superior to inferior, 7 cm from cornu to cornu, and 5.5 cm from anterior to posterior. The specimen weighs 380 gm. In the area of the left adnexa is an irregularly-shaped, lobular mass measuring 12 x 5 x 3 cm. Coursing along the anterior surface of the mass is a 7.5 cm-in-length x 0.5 cm-in-diameter edematous-appearing fallopian tube. Near the end of the left fallopian tube, is a 2.5 x 2 x 2 cm cyst with a thin (less than 0.1 cm), smooth wall. Opening the cyst releases a small amount of serous fluid. Sections of the fallopian tube show a tan-white wall and a putative slit-like lumen. Sectioning the mass shows firm, tan-white cut surfaces. The

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

mass does not appear to directly invade the fallopian tube wall. In addition to the main mass, there are two smaller masses on the anterior surface of the specimen, measuring 3.5 and 1.5 cm in greatest dimension, respectively. Both show firm, tan-white cut surfaces. Elsewhere, the serosa is tan and smooth, except at the former site of the right adnexa, where it is roughened. The ectocervix is smooth and tan-white to purple-tan. It measures 4 x 2 cm and shows a 0.6 cm ovoid os. Bivalving the uterus shows putative invasion of the myometrium near the left cornu by the mass. The endocervical canal measures 3.5 cm. The endometrial cavity measures 5 x 0.5 cm. Sections show an endometrial thickness of 0.5 cm and a myometrial thickness of 2.6 cm. The myometrium away from the infiltrating mass is unremarkable. No vaginal or bladder tissue is grossly identified. Labeled B1 to B6 - anterior strip (B1, 2 and B3, 4 are contiguous); B7 to B12 - posterior strip (B7, 8 and B9, 10 are contiguous); B13 - additional anterior cervix; B14 - additional posterior cervix; B15, 16 - mass infiltrating myometrium; B17, 18 - smaller anterior serosal masses; B19 - fallopian tube in relation to mass; B20 - cyst associated with fallopian tube.

The third container is labeled "#3 right fallopian tube/ovary." It holds an irregularly-shaped piece of firm to fibrous, tan to purple-tan tissue measuring 10 x 6.5 x 5.5 cm and weighing 165 gm. The surface of the piece of tissue shows numerous small papillary excrescences, which are inked. Away from the excrescences, the surface is smooth. A fallopian tube is not identified. Sectioning the tissue shows primarily solid, firm, tan-white cut surfaces consistent with neoplasm. There are also a few smooth-walled cystic spaces, measuring up to 2 cm in diameter. Labeled C1, 2 - inked surface excrescences; C3 to C5 - solid areas; C6 - cyst wall.

The fourth container is labeled "#4 rectal tumor." It holds three irregularly-shaped pieces of firm, tan-white tissue, consistent with tumor. The pieces have a small amount of adherent yellow-tan to gray-white fibrofatty tissue, and they measure 11 x 7 x 4.5 cm in aggregate. Sectioning the pieces of tissue shows firm, off-white cut surfaces. No definitive bowel is identified. Labeled D1 to D3 - one section from each piece.

The fifth container is labeled "#5 right pelvic lymph nodes." It holds a single irregularly-shaped piece of firm, tan-white to yellow-tan to tan-brown tissue measuring 7.5 x 4.5 x 2 cm. Sectioning the tissue shows a single large, firm lymph node measuring 4.5 x 3.5 x 1.9 cm. Sections show a hemorrhagic, necrotic center. Sectioning the remainder of the tissue shows a smaller, firm putative lymph node measuring 0.5 x 0.2 x 0.1 cm, and several poorly-defined, slightly firmer areas that may also represent lymph nodes infiltrated with fat. Labeled E1, 2 - representative sections of largest node; E3 - smaller putative node; E4 to E6 - firm areas of fatty tissue.

The sixth container is labeled "#6 left pelvic lymph nodes." It holds several pieces of yellow-tan to tan-brown to gray-tan tissue measuring 7.2 x 4.5 x 1.7 cm in aggregate. Sectioning the tissue shows three large, ovoid putative lymph nodes, measuring between 4 x 1.5 x 1.5 cm and 3.5 x 1.7 x 1.6 cm, and a much smaller, firm putative node measuring 0.5 x 0.5 x 0.5 cm. Sectioning the three larger nodes shows firm, off-white cut surfaces and degenerated, cystic areas, consistent with involvement by metastatic carcinoma. Labeled F1 to F3 - sections of three large lymph nodes; F4 - smaller node, entirely submitted.

The seventh container is labeled "#7 left periaortic lymph nodes." It holds two pieces of firm, gray-white to yellow-tan to tan-brown tissue measuring 3.5 x 2.5 x 2.5 cm. Sections show four firm putative lymph nodes measuring between 2.6 x 1.6 x 1.5 cm and 1.1 x 0.7 x 0.5 cm. Sectioning the largest putative node shows a firm, gray-white cut surface consistent with involvement by metastatic carcinoma. Labeled G1 - section of largest node; G2 - three smaller nodes, entirely submitted; G3 - remaining fatty tissue.

The eighth container is labeled "#8 right periaortic lymph node." It holds an irregularly-shaped, lobulated, firm putative lymph node measuring 7.5 x 3.5 x 2.5 cm. On sectioning, this large node actually appears to represent two separate nodes involved by metastatic carcinoma, measuring 3.5 and 2.9 cm in greatest dimension, respectively. Also in the container are three additional, much smaller putative lymph nodes, measuring between 1 x 0.9 x 0.5 cm and 0.6 x 0.5 x 0.2 cm. Labeled H1, 2 - representative sections of the two largest, matted lymph nodes; H3 - three smaller putative nodes; H4 - one smaller putative node.

The ninth container is labeled "#9 gastrocolic omentum." It holds a portion of omentum measuring 36 x 15 x 1.5 cm. Several firm, gray-white nodules are noted on the omental surface, consistent with metastatic disease. The largest of these measures 3.7 x 2.5 x 1.6 cm. Labeled I. Jar 3.

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

[page 4 of 4]
TCGA-24-1842

SURGICAL PATHOLOGY REPORT

HISTOPATHOLOGIC TYPE

The histologic diagnosis is high grade serous carcinoma

HISTOLOGIC GRADE

The histologic grade is poorly differentiated (G3)

TUMOR SITES

bilateral ovaries

TUMOR INVOLVEMENT

Metastatic involvement of the omentum is present

TUMOR SIZE

The maximum dimension of tumor implants outside the true pelvis is greater than or equal to 2 cm

PRIMARY TUMOR (T)

Based on the above information, the primary tumor is classified as macroscopic peritoneal metastasis beyond pelvis more than 2 cm in greatest dimension or regional lymph node metastasis (T3c/IIIC)

REGIONAL LYMPH NODES (N)

The regional lymph nodes are classified as regional lymph node metastasis (N1)

The total number of regional lymph nodes examined is 20

The total number of metastatically-involved lymph nodes is 27

Extranodal extension by tumor metastases is present

DISTANT METASTASIS (M)

The status of distant tumor site cannot be assessed (MX)

STAGE GROUPING

The Final AJCC/UICC/FIGO stage is pT3c/N1/M0 (Stage IIIC)

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Source: NCI Genomic Data Commons file 49c7d076-7ffe-482e-860b-872e57fa263e (TCGA-24-1842.3465AAE7-0664-44E5-A27F-C02FD73526A1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).